Somatic mutation profile of tumor specimen TCGA-EL-A3H5-01A (aliquot TCGA-EL-A3H5-01A-11D-A202-08) from TCGA case TCGA-EL-A3H5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.3 years (20,926 days).
Specimen TCGA-EL-A3H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99d38297-6974-4e68-9889-2a28fbfef74e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H5-10A (Blood Derived Normal), aliquot TCGA-EL-A3H5-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e44f2b1c-adc0-465a-96a2-9a6494039ac0

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 13, Silent 10, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARID3B | c.1232G>A p.S411N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60557974; called by muse, mutect2, varscan2
- BEX3 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV55421891; called by muse, mutect2, varscan2
- BRCA2 | c.8212G>T p.A2738S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV66463973; called by muse, mutect2, varscan2
- C11orf87 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV59358837; called by muse, mutect2, varscan2
- MAP3K6 | c.2581C>T p.Q861* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV58875052; called by muse, mutect2, varscan2
- NPHS1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs386833934, CM101330, CM109677, COSV62290293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121L12 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as rs991828786, COSV68692350; called by muse, mutect2, varscan2
- PRKCSH | c.1265+1G>T p.X422_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as COSV52954615; called by muse, mutect2, varscan2
- SEMA6B | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56703535; called by muse, mutect2, varscan2
- SENP5 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60211041; called by muse, mutect2, varscan2
- STOML1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV51455749, COSV99166749; called by muse, mutect2
- USP9X | c.5393A>C p.K1798T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61076828; called by muse, mutect2, varscan2
- ZNF311 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65853526; called by muse, mutect2, varscan2
- ZXDC | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100306301, COSV60449137; called by muse, mutect2, varscan2
- ZNHIT6 | c.875del p.S292Lfs*6 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- ABCA6 | c.2445G>T p.L815= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV52646927; called by muse, mutect2, varscan2
- ALDH1B1 | c.1017C>T p.T339= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs1017877479, COSV66620577, COSV66620783; called by muse, mutect2, varscan2
- ASPM | c.9579C>T p.R3193= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV54141376; called by muse, mutect2, varscan2
- HHAT | c.736C>T p.L246= | Silent (SNP) | VAF 51/237 reads (22%) | catalogued as COSV54803655, COSV54812546; called by muse, mutect2, varscan2
- KRT36 | c.900G>A p.E300= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60205073; called by muse, mutect2, varscan2
- LONRF1 | c.2223A>G p.P741= | Silent (SNP) | VAF 54/208 reads (26%) | catalogued as rs770005318, COSV68038229; called by muse, mutect2, varscan2
- MESD | c.61C>T p.L21= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55726713; called by muse, mutect2
- NHS | c.1089T>A p.V363= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as COSV66284850; called by muse, mutect2, varscan2
- NYNRIN | c.574C>T p.L192= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs766168636, COSV66845708; called by muse, mutect2, varscan2
- ZBTB22 | c.1710C>T p.G570= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1462226803, COSV56473568; called by muse, mutect2, varscan2
